Somatic mutation profile of tumor specimen ALCH-B34Y-TTP1-A (aliquot ALCH-B34Y-TTP1-A-1-0-D-A78R-36) from ALCHEMIST case ALCH-B34Y, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.5 years (25,376 days).
Specimen ALCH-B34Y-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 060f78af-866b-427f-ad9f-523ee6552ee1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B34Y-NB1-A (Blood Derived Normal), aliquot ALCH-B34Y-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/371a61ad-bc43-4f48-85ae-9e2aa6a3c30d

The open-access MAF lists 427 somatic variants for this specimen: 295 protein-altering or splice-affecting, 88 silent, 44 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 252, Silent 88, Intron 20, Nonsense Mutation 18, Frame Shift Del 12, 3'Flank 8, 5'UTR 7, RNA 6, Splice Site 4, Splice Region 4, Frame Shift Ins 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 152/670 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACSM5 | c.1264del p.R422Vfs*53 | Frame Shift Del (DEL) | VAF 57/442 reads (13%) | catalogued as rs768797930; called by mutect2, pindel, varscan2
- ACTRT2 | c.397G>T p.V133L | Missense Mutation (SNP) | VAF 45/216 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV65760423; called by muse, mutect2, varscan2
- ADAMTS2 | c.1868G>A p.R623H | Missense Mutation (SNP) | VAF 81/501 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1218632514; called by muse, mutect2, varscan2
- ADGRL3 | c.3007G>C p.D1003H (on ENST00000506720 / NM_001322402.2; = p.D935H on NM_015236.6) | Missense Mutation (SNP) | VAF 48/225 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.542); catalogued as COSV72230345; called by muse, mutect2, varscan2
- AXDND1 | c.1135T>C p.Y379H | Missense Mutation (SNP) | VAF 61/365 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as rs569825439; called by muse, mutect2, varscan2
- BCL6B | c.1291G>T p.V431F | Missense Mutation (SNP) | VAF 63/319 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV53428446; called by muse, mutect2, varscan2
- BNC2 | c.1516C>T p.R506* | Nonsense Mutation (SNP) | VAF 148/747 reads (20%) | catalogued as COSV66146939, COSV66156760; called by muse, mutect2, varscan2
- BTBD11 | c.2635G>A p.E879K (on ENST00000280758 / NM_001018072.2; = p.E416K on NM_001017523.2) | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV55038944; called by muse, mutect2, varscan2
- C1orf141 | c.215G>A p.S72N | Missense Mutation (SNP) | VAF 92/480 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as COSV63992019; called by muse, mutect2, varscan2
- CALCRL | c.1334G>T p.S445I | Missense Mutation (SNP) | VAF 89/533 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.11); catalogued as COSV66475523; called by muse, mutect2, varscan2
- CCDC136 | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 46/244 reads (19%) | catalogued as rs780809914, COSV52797716; called by muse, mutect2, varscan2
- CD180 | c.30G>A p.W10* | Nonsense Mutation (SNP) | VAF 85/613 reads (14%) | catalogued as rs753346543; called by muse, mutect2, varscan2
- CDH7 | c.1494+1G>A p.X498_splice | Splice Site (SNP) | VAF 64/349 reads (18%) | catalogued as rs759202083; called by muse, mutect2, varscan2
- CHIT1 | c.197T>A p.L66Q | Missense Mutation (SNP) | VAF 203/1374 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs767221532; called by muse, mutect2, varscan2
- CKM | c.286C>A p.R96S | Missense Mutation (SNP) | VAF 72/421 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as COSV55531766; called by muse, mutect2, varscan2
- CMTM2 | c.208C>G p.R70G | Missense Mutation (SNP) | VAF 75/463 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.446); catalogued as rs1371116420; called by muse, varscan2
- CSMD1 | c.4300C>A p.Q1434K (on ENST00000520002; = p.Q1433K on NM_033225.6) | Missense Mutation (SNP) | VAF 41/206 reads (20%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.874); catalogued as COSV59337241; called by muse, mutect2, varscan2
- CXCR1 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 59/367 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as rs898598822; called by muse, mutect2, varscan2
- DCHS1 | c.4735C>A p.R1579S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV55041400; called by muse, mutect2, varscan2
- DDX60 | c.4009G>A p.V1337I | Missense Mutation (SNP) | VAF 61/390 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.52); catalogued as rs371710589; called by muse, mutect2, varscan2
- E2F7 | c.302G>T p.R101L | Missense Mutation (SNP) | VAF 105/493 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV59737344; called by muse, mutect2, varscan2
- ELAPOR2 | c.2792G>T p.G931V (on ENST00000450689 / NM_001142749.3; = p.G764V on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/280 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.767); catalogued as COSV99787969; called by muse, mutect2, varscan2
- EZH1 | c.562G>T p.D188Y | Missense Mutation (SNP) | VAF 68/538 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as COSV101331394; called by muse, mutect2, varscan2
- FAM131B | c.242G>C p.R81P | Missense Mutation (SNP) | VAF 86/487 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV101281778; called by muse, mutect2, varscan2
- FILIP1 | c.2992G>A p.A998T | Missense Mutation (SNP) | VAF 30/557 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs962312690; called by muse, mutect2
- FLYWCH2 | c.246G>T p.Q82H | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.362); catalogued as rs1242442050; called by muse, mutect2, varscan2
- FUT5 | c.1109C>A p.A370E | Missense Mutation (SNP) | VAF 46/285 reads (16%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.59); catalogued as rs200448911, COSV99398935; called by muse, mutect2, varscan2
- GLI1 | c.1711C>A p.P571T | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.906); catalogued as rs1275055587; called by muse, mutect2, varscan2
- GLI3 | c.3397G>T p.G1133W | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV67884684; called by muse, mutect2, varscan2
- GOLGA4 | c.1801C>T p.H601Y | Missense Mutation (SNP) | VAF 44/284 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs367827056; called by muse, mutect2, varscan2
- GRIK4 | c.2645G>A p.R882Q | Missense Mutation (SNP) | VAF 48/267 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.267); catalogued as rs903181974; called by muse, mutect2, varscan2
- HOXD12 | c.589G>T p.A197S | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV66832308; called by muse, mutect2, varscan2
- IL15RA | c.693-1G>A p.X231_splice | Splice Site (SNP) | VAF 68/332 reads (20%) | catalogued as COSV101181941; called by muse, mutect2, varscan2
- IL9R | c.494C>A p.T165N | Missense Mutation (SNP) | VAF 98/574 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as COSV99729836; called by muse, mutect2, varscan2
- KALRN | c.7775C>A p.P2592H (on ENST00000360013 / NM_001024660.4; = p.P895H on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/322 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756968542; called by muse, mutect2, varscan2
- KCNH1 | c.2482G>T p.G828W (on ENST00000271751 / NM_172362.3; = p.G801W on NM_002238.4) | Missense Mutation (SNP) | VAF 38/268 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.473); catalogued as COSV55087902, COSV99662329; called by muse, mutect2, varscan2
- KCNH1 | c.1412C>A p.P471Q (on ENST00000271751 / NM_172362.3; = p.P444Q on NM_002238.4) | Missense Mutation (SNP) | VAF 76/209 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV99657908; called by muse, mutect2
- KRT79 | c.464C>A p.S155Y | Missense Mutation (SNP) | VAF 46/320 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57942115; called by muse, mutect2, varscan2
- KRTAP6-3 | c.209G>T p.G70V | Missense Mutation (SNP) | VAF 126/959 reads (13%) | PolyPhen possibly damaging (0.783); catalogued as COSV66963286; called by muse, mutect2, varscan2
- LARP1B | c.355C>T p.R119* | Nonsense Mutation (SNP) | VAF 42/224 reads (19%) | catalogued as rs753096211; called by muse, mutect2, varscan2
- LAYN | c.481del p.A161Lfs*18 (on ENST00000375615 / NM_001258390.1; = p.A153Lfs*18 on NM_178834.5) | Frame Shift Del (DEL) | VAF 29/212 reads (14%) | catalogued as COSV65105571; called by mutect2, pindel, varscan2
- MAMDC2 | c.369C>G p.D123E | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.366); catalogued as rs1304241403; called by muse, mutect2, varscan2
- MAST3 | c.2674C>T p.R892C | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs1178040525, COSV99444313; called by muse, mutect2, varscan2
- MCF2L2 | c.2658G>A p.M886I | Missense Mutation (SNP) | VAF 79/445 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1160815249, COSV61058826; called by muse, mutect2, varscan2
- ME1 | c.229G>T p.D77Y | Missense Mutation (SNP) | VAF 60/255 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV100866559; called by muse, mutect2
- MMP2 | c.381G>T p.R127S | Missense Mutation (SNP) | VAF 143/855 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.626); catalogued as COSV99527446; called by muse, mutect2, varscan2
- MORF4L2 | c.584G>T p.G195V | Missense Mutation (SNP) | VAF 75/256 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100846373; called by muse, mutect2, varscan2
- MTOR | c.2319G>C p.E773D | Missense Mutation (SNP) | VAF 61/402 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.121); catalogued as rs367653056, COSV63878500; called by muse, mutect2, varscan2
- MUC16 | c.11998C>A p.P4000T | Missense Mutation (SNP) | VAF 54/435 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.556); catalogued as COSV67488522; called by muse, mutect2, varscan2
- MUC5AC | c.15338G>C p.G5113A | Missense Mutation (SNP) | VAF 97/499 reads (19%) | SIFT tolerated (1); PolyPhen possibly damaging (0.553); catalogued as COSV100611648; called by muse, mutect2, varscan2
- MYCBPAP | c.670G>A p.V224M | Missense Mutation (SNP) | VAF 104/495 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.201); catalogued as COSV60407898; called by muse, mutect2, varscan2
- MYH1 | c.4582C>A p.H1528N | Missense Mutation (SNP) | VAF 82/531 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.073); catalogued as COSV56848573; called by muse, mutect2, varscan2
- NAV3 | c.4901T>C p.I1634T | Missense Mutation (SNP) | VAF 75/442 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as rs1208413675, COSV99885969; called by muse, mutect2, varscan2
- NKX3-2 | c.808C>G p.L270V | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs771207509, COSV66711681; called by muse, mutect2, varscan2
- NLRP12 | c.2794G>T p.G932C | Missense Mutation (SNP) | VAF 80/432 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as COSV100144895, COSV100144982; called by muse, mutect2, varscan2
- NOL7 | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 77/309 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.253); catalogued as rs1296468325; called by muse, mutect2, varscan2
- NRG1 | c.204C>A p.S68R (on ENST00000523534; = p.S215R on NM_013962.2) | Missense Mutation (SNP) | VAF 48/333 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.75); catalogued as rs750334304; called by muse, mutect2, varscan2
- NUP153 | c.2327G>T p.S776I | Missense Mutation (SNP) | VAF 64/381 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV50455989; called by muse, mutect2, varscan2
- OBSCN | c.17020del p.A5674Pfs*21 | Frame Shift Del (DEL) | VAF 71/239 reads (30%) | catalogued as rs757737800; called by mutect2, pindel, varscan2
- OR13H1 | c.770T>C p.M257T | Missense Mutation (SNP) | VAF 66/170 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as rs1222328025; called by muse, mutect2, varscan2
- OR2W1 | c.272C>A p.T91N | Missense Mutation (SNP) | VAF 73/315 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as rs745321754; called by muse, mutect2, varscan2
- OR2W3 | c.454G>C p.G152R | Missense Mutation (SNP) | VAF 52/397 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100831766; called by muse, mutect2, varscan2
- OR56A3 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 63/300 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61569500; called by muse, mutect2
- OR6N1 | c.771del p.M258Cfs*5 | Frame Shift Del (DEL) | VAF 50/333 reads (15%) | catalogued as COSV58648002; called by mutect2, pindel, varscan2
- OR8H1 | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 99/603 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.238); catalogued as COSV100477459; called by muse, mutect2, varscan2
- PHEX | c.1549G>T p.D517Y | Missense Mutation (SNP) | VAF 157/423 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.921); catalogued as COSV65076760; called by muse, mutect2, varscan2
- POU4F1 | c.745G>A p.V249M | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.477); catalogued as rs1181558761; called by muse, mutect2, varscan2
- PRKACG | c.101C>A p.P34H | Missense Mutation (SNP) | VAF 64/336 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV99598562; called by muse, mutect2, varscan2
- PRKCG | c.1146G>C p.L382F | Missense Mutation (SNP) | VAF 18/568 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54724619; called by muse, mutect2
- PRPH2 | c.346G>C p.A116P | Missense Mutation (SNP) | VAF 85/387 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as CM157918; called by muse, mutect2, varscan2
- PTPRD | c.2305A>T p.M769L | Missense Mutation (SNP) | VAF 82/619 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs1333470758; called by muse, mutect2, varscan2
- RABGGTA | c.1262A>G p.Y421C | Missense Mutation (SNP) | VAF 32/245 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1167945173; called by muse, mutect2
- RBBP6 | c.4508G>T p.R1503L | Missense Mutation (SNP) | VAF 48/259 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); catalogued as COSV100154539, COSV60506340; called by muse, mutect2, varscan2
- RBM10 | c.1618C>T p.Q540* | Nonsense Mutation (SNP) | VAF 149/366 reads (41%) | catalogued as COSV61308913; called by muse, mutect2, varscan2
- RGS2 | c.563G>C p.R188P | Missense Mutation (SNP) | VAF 130/1071 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs369752935; called by muse, mutect2, varscan2
- RNASEH2B | c.311C>G p.A104G | Missense Mutation (SNP) | VAF 131/922 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs1389819327; called by muse, mutect2, varscan2
- SCN5A | c.655C>A p.R219S | Missense Mutation (SNP) | VAF 54/286 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV61116418; called by muse, mutect2
- SCNN1G | c.1321G>A p.A441T | Missense Mutation (SNP) | VAF 109/711 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.516); catalogued as rs757595333; called by muse, mutect2, varscan2
- SI | c.4280G>C p.R1427T | Missense Mutation (SNP) | VAF 92/487 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as COSV100016935, COSV52302260; called by muse, mutect2, varscan2
- SLC18A2 | c.1120T>A p.C374S | Missense Mutation (SNP) | VAF 53/373 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.744); catalogued as rs1326409698; called by muse, mutect2, varscan2
- SLC19A3 | c.1051G>T p.V351F | Missense Mutation (SNP) | VAF 14/345 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV51453717; called by muse, mutect2
- SLC22A10 | c.1395G>T p.R465S | Missense Mutation (SNP) | VAF 90/383 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as COSV60423781; called by muse, mutect2, varscan2
- SLC25A11 | c.394A>T p.T132S | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV99337463; called by muse, mutect2
- SLC7A13 | c.360C>G p.I120M | Missense Mutation (SNP) | VAF 63/275 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); catalogued as COSV52533038; called by muse, mutect2, varscan2
- SLCO1A2 | c.1617G>T p.M539I | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56604485; called by muse, mutect2, varscan2
- SMUG1 | c.617G>T p.G206V | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); catalogued as rs749455649; called by muse, mutect2, varscan2
- ST8SIA3 | c.1031C>A p.T344N | Missense Mutation (SNP) | VAF 76/588 reads (13%) | PolyPhen benign (0.1); catalogued as rs1357356878, COSV60654126; called by muse, mutect2, varscan2
- TACC2 | c.6595C>T p.P2199S (on ENST00000334433; = p.P277S on NM_006997.4) | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.139); catalogued as rs760120159, COSV53282613; called by muse, mutect2, varscan2
- TCTE3 | c.543C>A p.H181Q | Missense Mutation (SNP) | VAF 74/369 reads (20%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.93); catalogued as COSV64656317; called by muse, mutect2, varscan2
- TET1 | c.276G>T p.Q92H | Missense Mutation (SNP) | VAF 73/392 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.02); catalogued as COSV65382984; called by muse, mutect2, varscan2
- THAP9 | c.88A>G p.T30A | Missense Mutation (SNP) | VAF 20/372 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as rs758566957; called by muse, mutect2
- TSC22D3 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 95/259 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs144619048; called by muse, mutect2, varscan2
- USH2A | c.6341C>A p.T2114K | Missense Mutation (SNP) | VAF 165/1118 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV56372354; called by muse, mutect2, varscan2
- WDFY3 | c.2468C>T p.P823L | Missense Mutation (SNP) | VAF 69/307 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs762886259, COSV55703123; called by muse, mutect2, varscan2
- ZFP82 | c.793G>C p.V265L | Missense Mutation (SNP) | VAF 70/373 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0.225); catalogued as COSV67564947; called by muse, mutect2, varscan2
- ZFPM1 | c.1673C>A p.A558E | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs1182217127; called by muse, mutect2, varscan2
- ZNF213 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 49/244 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs144927484; called by muse, mutect2, varscan2
- ZNF251 | c.960del p.Y321Tfs*16 | Frame Shift Del (DEL) | VAF 43/256 reads (17%) | catalogued as COSV99478834; called by mutect2, pindel, varscan2
- ZNF536 | c.2041C>A p.Q681K | Missense Mutation (SNP) | VAF 56/316 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.952); catalogued as COSV62834801; called by muse, mutect2, varscan2
- ZNF90 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 32/372 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1448980832; called by muse, mutect2
- ZP4 | c.253G>T p.V85L | Missense Mutation (SNP) | VAF 94/620 reads (15%) | SIFT tolerated (0.97); PolyPhen benign (0.005); catalogued as rs772372321, COSV100850773, COSV63912858; called by muse, mutect2, varscan2
- A2ML1 | c.308_313del p.N103_N104del | In Frame Del (DEL) | VAF 24/170 reads (14%) | called by mutect2, pindel, varscan2
- ABCA1 | c.3040C>A p.Q1014K | Missense Mutation (SNP) | VAF 38/933 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.105); called by muse, mutect2
- ABCC1 | c.2197G>T p.E733* | Nonsense Mutation (SNP) | VAF 62/396 reads (16%) | called by muse, mutect2, varscan2
- ADAM11 | c.1132C>A p.L378M | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ADAM32 | c.834T>A p.I278= | Splice Region (SNP) | VAF 53/286 reads (19%) | called by muse, mutect2, varscan2
- ADAMTSL1 | c.5063A>G p.Q1688R | Missense Mutation (SNP) | VAF 85/499 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- ADGRE1 | c.1300G>T p.D434Y | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, varscan2
- ADRA1A | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 98/485 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- AHNAK2 | c.8334C>A p.S2778R | Missense Mutation (SNP) | VAF 72/460 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- AK9 | c.1896G>A p.W632* | Nonsense Mutation (SNP) | VAF 16/438 reads (4%) | called by muse, mutect2
- ANKRD30B | c.1462G>C p.E488Q | Missense Mutation (SNP) | VAF 60/434 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.266); called by muse, varscan2
- AP2B1 | c.1126G>A p.A376T | Missense Mutation (SNP) | VAF 54/337 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- ATP10B | c.223A>G p.K75E | Missense Mutation (SNP) | VAF 86/238 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- C16orf78 | c.244C>A p.R82S | Missense Mutation (SNP) | VAF 60/338 reads (18%) | SIFT tolerated (0.81); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- C1QA | c.684G>T p.Q228H | Missense Mutation (SNP) | VAF 56/277 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C1orf94 | c.1477C>T p.P493S (on ENST00000488417 / NM_001134734.2; = p.P303S on NM_032884.5) | Missense Mutation (SNP) | VAF 17/344 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- C2CD2L | c.2105A>G p.N702S | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C2orf66 | c.7A>G p.R3G | Missense Mutation (SNP) | VAF 76/449 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CACNA1C | c.5924T>C p.L1975P (on ENST00000399634 / NM_001167625.1; = p.L1904P on NM_000719.7) | Missense Mutation (SNP) | VAF 177/868 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- CACNA1E | c.841G>T p.D281Y | Missense Mutation (SNP) | VAF 90/660 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- CACNA1S | c.5094del p.T1699Pfs*24 | Frame Shift Del (DEL) | VAF 114/852 reads (13%) | called by mutect2, varscan2
- CACNA1S | c.5093C>A p.A1698D | Missense Mutation (SNP) | VAF 116/848 reads (14%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.01); called by mutect2, varscan2
- CALB1 | c.164C>A p.S55* | Nonsense Mutation (SNP) | VAF 101/568 reads (18%) | called by muse, mutect2, varscan2
- CAMK4 | c.970C>A p.R324S | Missense Mutation (SNP) | VAF 63/361 reads (17%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- CCDC120 | c.1535G>T p.R512L | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- CCDC59 | c.257C>T p.T86I | Missense Mutation (SNP) | VAF 102/691 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- CD177 | c.524G>A p.R175K | Missense Mutation (SNP) | VAF 33/362 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.209); called by muse, varscan2
- CDH7 | c.1494G>A p.Q498= | Splice Region (SNP) | VAF 64/355 reads (18%) | called by muse, mutect2, varscan2
- CGRRF1 | c.137A>G p.N46S | Missense Mutation (SNP) | VAF 65/291 reads (22%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CHD5 | c.2105C>A p.P702Q | Missense Mutation (SNP) | VAF 41/203 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- CIAO1 | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- CIAO3 | c.230G>T p.C77F | Missense Mutation (SNP) | VAF 72/422 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CLCN4 | c.1909G>T p.V637L | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CLIP4 | c.1259C>T p.A420V | Missense Mutation (SNP) | VAF 149/812 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLNK | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 50/384 reads (13%) | called by muse, mutect2, varscan2
- CNTNAP4 | c.2005A>T p.T669S | Missense Mutation (SNP) | VAF 94/513 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CRACR2A | c.1439C>A p.P480H | Missense Mutation (SNP) | VAF 84/374 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYP17A1 | c.685C>A p.L229M | Missense Mutation (SNP) | VAF 79/609 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- CYP4F3 | c.516C>G p.N172K | Missense Mutation (SNP) | VAF 53/313 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- DAAM2 | c.234G>T p.W78C | Missense Mutation (SNP) | VAF 133/835 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DACT1 | c.383A>G p.Q128R | Missense Mutation (SNP) | VAF 82/396 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- DCDC1 | c.4223A>T p.H1408L (on ENST00000597505 / NM_001367979.1; = p.H515L on NM_020869.3) | Missense Mutation (SNP) | VAF 151/803 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- DEFB113 | c.195G>C p.W65C | Missense Mutation (SNP) | VAF 101/367 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- DLEC1 | c.796G>T p.E266* | Nonsense Mutation (SNP) | VAF 144/751 reads (19%) | called by muse, mutect2, varscan2
- DOCK10 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 56/358 reads (16%) | called by muse, mutect2, varscan2
- DST | c.2576A>T p.Q859L (on ENST00000361203 / NM_001374722.1; = p.Q533L on NM_001723.6) | Missense Mutation (SNP) | VAF 62/423 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- EYS | c.551C>A p.S184Y | Missense Mutation (SNP) | VAF 64/345 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FAM160A1 | c.2050del p.L684Sfs*45 | Frame Shift Del (DEL) | VAF 39/236 reads (17%) | called by mutect2, pindel, varscan2
- FAM47A | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- FAM74A7 | n.653A>G | Splice Region (SNP) | VAF 50/500 reads (10%) | called by muse, mutect2, varscan2
- FAM83C | c.700A>G p.T234A | Missense Mutation (SNP) | VAF 40/213 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- FAM83D | c.663_665delinsCT p.R222* | Frame Shift Del (DEL) | VAF 50/274 reads (18%) | called by pindel, varscan2*
- FBXW8 | c.148G>T p.V50L (on ENST00000309909; = p.V88L on NM_012174.1) | Missense Mutation (SNP) | VAF 58/308 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- FIGNL1 | c.1085G>T p.G362V | Missense Mutation (SNP) | VAF 38/254 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FOSL2 | c.83G>A p.S28N | Missense Mutation (SNP) | VAF 74/351 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- FOXJ3 | c.805C>T p.Q269* | Nonsense Mutation (SNP) | VAF 73/420 reads (17%) | called by muse, mutect2, varscan2
- FOXL1 | c.562G>T p.A188S | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FRG2C | c.829G>C p.A277P | Missense Mutation (SNP) | VAF 111/802 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- FSIP2 | c.19224C>G p.H6408Q | Missense Mutation (SNP) | VAF 41/283 reads (14%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- GAB4 | c.836A>G p.H279R | Missense Mutation (SNP) | VAF 174/808 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- GALNT13 | c.437T>A p.L146Q | Missense Mutation (SNP) | VAF 63/331 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- GC | c.226G>T p.A76S | Missense Mutation (SNP) | VAF 46/238 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- GLI1 | c.1712C>A p.P571Q | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- GLRB | c.594G>C p.K198N | Missense Mutation (SNP) | VAF 132/724 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- GOLGA8T | c.1753del p.Q585Kfs*? | Frame Shift Del (DEL) | VAF 73/478 reads (15%) | called by mutect2, varscan2
- GPAT2 | c.1340G>T p.S447I | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- GPD2 | c.1036dup p.W346Lfs*11 | Frame Shift Ins (INS) | VAF 105/574 reads (18%) | called by mutect2, pindel, varscan2
- GPR12 | c.1005G>C p.*335Yext*21 | Nonstop Mutation (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2
- GPR150 | c.296G>C p.G99A | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- GPRIN3 | c.1574G>T p.G525V | Missense Mutation (SNP) | VAF 53/382 reads (14%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- HEATR9 | c.41G>T p.R14M | Missense Mutation (SNP) | VAF 39/282 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- HECW1 | c.2380C>A p.P794T | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- HMCN1 | c.15719G>T p.R5240I | Missense Mutation (SNP) | VAF 84/522 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HP | c.217del p.Q73Sfs*3 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | called by mutect2, varscan2
- IKBIP | c.898G>T p.D300Y | Missense Mutation (SNP) | VAF 32/262 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- IQCD | c.188T>A p.V63E | Missense Mutation (SNP) | VAF 32/210 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- JAKMIP1 | c.2307C>G p.I769M | Missense Mutation (SNP) | VAF 79/494 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- JAKMIP1 | c.1464C>A p.F488L | Missense Mutation (SNP) | VAF 109/475 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- KALRN | c.3469C>A p.H1157N | Missense Mutation (SNP) | VAF 55/492 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- KCNMB1 | c.461C>A p.P154H | Missense Mutation (SNP) | VAF 85/491 reads (17%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KCNS2 | c.749C>A p.P250H | Missense Mutation (SNP) | VAF 119/483 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KDM4D | c.998A>G p.Y333C | Missense Mutation (SNP) | VAF 59/246 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KEL | c.106G>T p.V36L | Missense Mutation (SNP) | VAF 98/522 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF21A | c.777G>T p.Q259H | Missense Mutation (SNP) | VAF 79/567 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- KLC1 | c.790G>T p.V264L | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- KRT71 | c.343C>T p.L115F | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LARGE1 | c.159G>T p.R53S | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- LCE1F | c.191_192insCTGCTGCAGCTCTCGGGG p.G64_G65insCCSSRG | In Frame Ins (INS) | VAF 53/443 reads (12%) | called by pindel, varscan2*
- LCOR | c.3075G>T p.R1025S | Missense Mutation (SNP) | VAF 50/236 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LDB3 | c.986C>A p.P329H | Missense Mutation (SNP) | VAF 121/613 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LIPI | c.959G>T p.R320L | Missense Mutation (SNP) | VAF 60/605 reads (10%) | SIFT tolerated (0.76); PolyPhen benign (0.022); called by muse, mutect2
- LMX1A | c.584C>A p.P195H | Missense Mutation (SNP) | VAF 66/503 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRFN3 | c.1680G>C p.M560I | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT tolerated (0.92); PolyPhen benign (0.001); called by muse, mutect2
- LRP1 | c.5352C>G p.S1784R | Missense Mutation (SNP) | VAF 42/193 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LRP1B | c.3827A>C p.H1276P | Missense Mutation (SNP) | VAF 68/382 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- LRRC8C | c.575A>T p.N192I | Missense Mutation (SNP) | VAF 93/495 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- LSAMP | c.926G>T p.G309V | Missense Mutation (SNP) | VAF 118/759 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- MAGEA11 | c.12G>T p.Q4H | Missense Mutation (SNP) | VAF 76/226 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- MAGEC1 | c.2107G>T p.D703Y | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- MCL1 | c.767A>T p.D256V | Missense Mutation (SNP) | VAF 145/1166 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ME1 | c.228G>T p.M76I | Missense Mutation (SNP) | VAF 60/251 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.01); called by muse, mutect2
- MEGF11 | c.596C>A p.P199H | Missense Mutation (SNP) | VAF 43/267 reads (16%) | SIFT tolerated (0.79); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MEGF8 | c.5623G>T p.D1875Y (on ENST00000251268 / NM_001271938.2; = p.D1808Y on NM_001410.3) | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MIF4GD | c.188T>C p.I63T (on ENST00000325102 / NM_001370592.1; = p.I97T on NM_020679.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/253 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- MINDY3 | c.724G>T p.G242* | Nonsense Mutation (SNP) | VAF 95/481 reads (20%) | called by muse, mutect2, varscan2
- MS4A4E | c.371del p.G124Afs*6 | Frame Shift Del (DEL) | VAF 51/323 reads (16%) | called by mutect2, pindel, varscan2
- MT1B | c.65A>G p.K22R | Missense Mutation (SNP) | VAF 102/605 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.554); called by mutect2, varscan2
- MUC16 | c.11999C>G p.P4000R | Missense Mutation (SNP) | VAF 52/433 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- MUC17 | c.11501C>A p.T3834K | Missense Mutation (SNP) | VAF 44/159 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- MUC4 | c.124G>C p.A42P | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.675); called by muse, mutect2
- MYO19 | c.1066G>T p.A356S | Missense Mutation (SNP) | VAF 77/423 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- MYOM2 | c.491C>A p.T164N | Missense Mutation (SNP) | VAF 68/384 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- NAA15 | c.869del p.G290Dfs*9 | Frame Shift Del (DEL) | VAF 57/369 reads (15%) | called by mutect2, pindel, varscan2
- NBEA | c.3211C>T p.L1071F | Missense Mutation (SNP) | VAF 72/340 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- NF1 | c.929A>G p.H310R | Missense Mutation (SNP) | VAF 100/525 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- NFATC2IP | c.1058A>T p.Q353L | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NFIC | c.1172A>T p.H391L | Missense Mutation (SNP) | VAF 33/199 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NOBOX | c.1739G>C p.G580A | Missense Mutation (SNP) | VAF 54/379 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- NOL4 | c.695C>G p.S232* | Nonsense Mutation (SNP) | VAF 36/283 reads (13%) | called by muse, mutect2, varscan2
- NOS3 | c.552C>A p.C184* | Nonsense Mutation (SNP) | VAF 21/146 reads (14%) | called by muse, mutect2, varscan2
- NPAS3 | c.2128G>T p.A710S (on ENST00000356141 / NM_001164749.2; = p.A678S on NM_022123.3) | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- OPN5 | c.41T>C p.L14P | Missense Mutation (SNP) | VAF 122/502 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR2AK2 | c.452G>T p.S151I | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2D3 | c.475T>A p.W159R | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR51I2 | c.724G>T p.V242L | Missense Mutation (SNP) | VAF 57/231 reads (25%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR56A3 | c.218T>C p.L73P | Missense Mutation (SNP) | VAF 62/298 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- P3H3 | c.1792T>A p.W598R | Missense Mutation (SNP) | VAF 68/333 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PADI6 | c.454C>A p.P152T | Missense Mutation (SNP) | VAF 35/235 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- PALM2AKAP2 | c.2344G>T p.E782* (on ENST00000259318 / NM_001136562.3; = p.E1013* on NM_007203.5) | Nonsense Mutation (SNP) | VAF 24/177 reads (14%) | called by muse, mutect2, varscan2
- PARVG | c.874G>T p.V292F | Missense Mutation (SNP) | VAF 75/424 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- PCDH7 | c.270G>T p.E90D | Missense Mutation (SNP) | VAF 46/242 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCDHGA4 | c.174G>T p.R58S | Missense Mutation (SNP) | VAF 64/402 reads (16%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- PDE4D | c.1862T>A p.L621Q (on ENST00000340635 / NM_001104631.2; = p.L485Q on NM_006203.4) | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- PDPR | c.608G>T p.G203V | Missense Mutation (SNP) | VAF 35/251 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PEX1 | c.780A>T p.K260N | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- PKHD1 | c.5083G>T p.V1695F | Missense Mutation (SNP) | VAF 187/1057 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- PLA2G4A | c.1648A>G p.S550G | Missense Mutation (SNP) | VAF 156/969 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- POLD3 | c.60+6C>T | Splice Region (SNP) | VAF 44/353 reads (12%) | called by muse, mutect2, varscan2
- PPP2R2B | c.17C>A p.P6H | Missense Mutation (SNP) | VAF 76/676 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- PPP2R2B | c.16C>A p.P6T | Missense Mutation (SNP) | VAF 73/667 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PRKDC | c.4282A>G p.I1428V | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT tolerated (0.81); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PROX1 | c.1768C>A p.L590I | Missense Mutation (SNP) | VAF 182/674 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PRRT3 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.051); called by muse, mutect2
- PRSS1 | c.702C>G p.N234K | Missense Mutation (SNP) | VAF 177/904 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- PTGER3 | c.479G>T p.R160M | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PTPRT | c.4260G>T p.M1420I | Missense Mutation (SNP) | VAF 53/248 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PUM1 | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- RELN | c.3848A>G p.D1283G | Missense Mutation (SNP) | VAF 212/1134 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RFPL3 | c.479C>A p.A160D (on ENST00000249007 / NM_001098535.1; = p.A131D on NM_006604.2) | Missense Mutation (SNP) | VAF 73/440 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- RGS22 | c.3445G>A p.V1149I | Missense Mutation (SNP) | VAF 43/261 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- RIMBP2 | c.2909C>G p.P970R | Missense Mutation (SNP) | VAF 99/494 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNASEL | c.1168G>T p.A390S | Missense Mutation (SNP) | VAF 203/1093 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF183 | c.112G>T p.V38L | Missense Mutation (SNP) | VAF 70/505 reads (14%) | SIFT tolerated (0.93); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RPTN | c.1030G>T p.G344C | Missense Mutation (SNP) | VAF 140/1118 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RYR2 | c.6469C>G p.Q2157E | Missense Mutation (SNP) | VAF 160/1045 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SAMHD1 | c.853-1G>A p.X285_splice | Splice Site (SNP) | VAF 102/624 reads (16%) | called by muse, mutect2, varscan2
- SCN5A | c.653T>A p.L218* | Nonsense Mutation (SNP) | VAF 54/285 reads (19%) | called by muse, mutect2
- SLAMF9 | c.47-1G>T p.X16_splice | Splice Site (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2
- SLC22A7 | c.1143G>C p.L381F (on ENST00000372585 / NM_153320.2; = p.L379F on NM_006672.3) | Missense Mutation (SNP) | VAF 61/199 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- SLC22A8 | c.348C>A p.C116* | Nonsense Mutation (SNP) | VAF 65/295 reads (22%) | called by muse, mutect2, varscan2
- SLC24A2 | c.660dup p.G221Wfs*8 | Frame Shift Ins (INS) | VAF 137/1021 reads (13%) | called by mutect2, pindel, varscan2
- SLC26A6 | c.1546C>G p.L516V | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC28A1 | c.176T>A p.F59Y | Missense Mutation (SNP) | VAF 63/310 reads (20%) | SIFT tolerated (0.91); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC51A | c.926T>C p.M309T | Missense Mutation (SNP) | VAF 61/355 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- SLCO2A1 | c.1663G>A p.V555M | Missense Mutation (SNP) | VAF 54/402 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- SMS | c.875G>C p.W292S | Missense Mutation (SNP) | VAF 110/378 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SND1 | c.931C>G p.L311V | Missense Mutation (SNP) | VAF 64/346 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SNU13 | c.14A>C p.Q5P | Missense Mutation (SNP) | VAF 16/398 reads (4%) | SIFT deleterious, low confidence (0); called by muse, mutect2
- SPATA31D1 | c.2530G>T p.G844C | Missense Mutation (SNP) | VAF 222/1145 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- SPATA31E1 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 46/309 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- TAS1R2 | c.910T>C p.W304R | Missense Mutation (SNP) | VAF 65/395 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TLE1 | c.978G>A p.M326I | Missense Mutation (SNP) | VAF 90/505 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM161B | c.1190A>G p.N397S | Missense Mutation (SNP) | VAF 71/216 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- TNFRSF11A | c.716G>T p.G239V | Missense Mutation (SNP) | VAF 114/585 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TNNI3K | c.1798G>T p.G600W | Missense Mutation (SNP) | VAF 120/704 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRAF3IP3 | c.77G>A p.R26K | Missense Mutation (SNP) | VAF 46/328 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- TRAJ52 | c.57G>T p.L19F | Missense Mutation (SNP) | VAF 102/477 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM51 | c.110C>A p.P37H | Missense Mutation (SNP) | VAF 90/550 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRPM2 | c.2290C>A p.P764T | Missense Mutation (SNP) | VAF 43/281 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TSHZ3 | c.122C>A p.P41H | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- TUBA3D | c.209T>A p.L70Q | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- UBA6 | c.2889A>T p.K963N | Missense Mutation (SNP) | VAF 73/490 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- UNC13C | c.5509G>T p.G1837W | Missense Mutation (SNP) | VAF 77/548 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- WDR90 | c.2042A>T p.H681L | Missense Mutation (SNP) | VAF 72/410 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.05); called by mutect2, varscan2
- XIRP1 | c.859C>A p.Q287K | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- YRDC | c.247G>C p.V83L | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZAR1 | c.788C>A p.P263Q | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZBED9 | c.911G>A p.S304N | Missense Mutation (SNP) | VAF 18/443 reads (4%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.051); called by muse, mutect2
- ZBTB40 | c.3091G>T p.D1031Y | Missense Mutation (SNP) | VAF 133/585 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZFP42 | c.721G>A p.G241R | Missense Mutation (SNP) | VAF 76/488 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- ZIC5 | c.185C>A p.P62Q | Missense Mutation (SNP) | VAF 75/369 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF716 | c.985T>A p.C329S | Missense Mutation (SNP) | VAF 110/748 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- ZNF726 | c.497G>T p.R166I | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.73); PolyPhen benign (0.088); called by muse, mutect2
- ACAN | c.2901C>T p.A967= | Silent (SNP) | VAF 134/699 reads (19%) | called by muse, varscan2
- ACTN3 | c.186A>T p.A62= | Silent (SNP) | VAF 32/164 reads (20%) | called by muse, mutect2, varscan2
- ADRB3 | c.1119C>A p.A373= | Silent (SNP) | VAF 29/135 reads (21%) | called by muse, mutect2, varscan2
- ANO6 | c.2388G>T p.P796= | Silent (SNP) | VAF 258/1134 reads (23%) | called by muse, mutect2, varscan2
- C16orf78 | c.372C>A p.I124= | Silent (SNP) | VAF 137/720 reads (19%) | catalogued as COSV54558004; called by muse, mutect2, varscan2
- C2orf78 | c.2490T>G p.T830= | Silent (SNP) | VAF 44/333 reads (13%) | called by muse, mutect2, varscan2
- CABYR | c.1257T>G p.L419= | Silent (SNP) | VAF 125/782 reads (16%) | called by muse, mutect2, varscan2
- CAND2 | c.1887C>A p.P629= (on ENST00000456430 / NM_001162499.2; = p.P536= on NM_012298.3) | Silent (SNP) | VAF 75/398 reads (19%) | called by muse, mutect2, varscan2
- CAPN15 | c.951G>T p.S317= | Silent (SNP) | VAF 16/97 reads (16%) | catalogued as COSV99562354; called by muse, mutect2, varscan2
- CATIP | c.1158G>A p.A386= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as rs1164309296; called by muse, mutect2, varscan2
- CCDC61 | c.495G>C p.L165= | Silent (SNP) | VAF 68/329 reads (21%) | called by muse, mutect2, varscan2
- CDH10 | c.1698G>A p.V566= | Silent (SNP) | VAF 270/923 reads (29%) | called by muse, mutect2, varscan2
- COL6A5 | c.5721T>C p.L1907= (on ENST00000312481; = p.L1903= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/106 reads (25%) | called by muse, mutect2
- COLGALT1 | c.222C>T p.L74= | Silent (SNP) | VAF 22/140 reads (16%) | called by muse, mutect2, varscan2
- COMMD1 | c.243A>G p.K81= | Silent (SNP) | VAF 103/431 reads (24%) | called by muse, mutect2, varscan2
- COPG1 | c.1038C>T p.T346= | Silent (SNP) | VAF 81/529 reads (15%) | catalogued as rs755207836; called by muse, mutect2, varscan2
- CRISP3 | c.408C>T p.A136= (on ENST00000371159 / NM_001368123.1; = p.A118= on NM_006061.4) | Silent (SNP) | VAF 83/461 reads (18%) | catalogued as rs1267190711; called by muse, mutect2, varscan2
- CYP17A1 | c.684C>A p.T228= | Silent (SNP) | VAF 78/606 reads (13%) | called by muse, mutect2, varscan2
- CYP4F2 | c.60G>T p.L20= | Silent (SNP) | VAF 54/232 reads (23%) | catalogued as COSV50001322; called by muse, mutect2, varscan2
- DDX51 | c.225G>T p.R75= | Silent (SNP) | VAF 8/41 reads (20%) | called by muse, mutect2, varscan2
- DOC2B | c.799C>A p.R267= | Silent (SNP) | VAF 40/268 reads (15%) | called by muse, mutect2, varscan2
- ERCC3 | c.525C>T p.Y175= | Silent (SNP) | VAF 36/237 reads (15%) | called by muse, mutect2, varscan2
- FOXE3 | c.105C>A p.A35= | Silent (SNP) | VAF 13/59 reads (22%) | called by muse, mutect2, varscan2
- FRAS1 | c.4137G>T p.V1379= | Silent (SNP) | VAF 24/114 reads (21%) | called by muse, mutect2, varscan2
- GLYATL1 | c.720G>A p.R240= (on ENST00000317391 / NM_001354699.1; = p.R271= on NM_080661.4) | Silent (SNP) | VAF 143/653 reads (22%) | called by muse, mutect2, varscan2
- GNAQ | c.882A>G p.E294= | Silent (SNP) | VAF 35/604 reads (6%) | called by muse, mutect2
- GOLGA6L6 | c.606A>T p.I202= | Silent (SNP) | VAF 31/261 reads (12%) | called by muse, mutect2, varscan2
- HIPK3 | c.912A>G p.Q304= | Silent (SNP) | VAF 60/276 reads (22%) | called by muse, varscan2
- HTR1D | c.348C>A p.S116= | Silent (SNP) | VAF 46/210 reads (22%) | called by muse, mutect2, varscan2
- IGHE | c.753G>A p.V251= | Silent (SNP) | VAF 63/417 reads (15%) | called by muse, mutect2, varscan2
- INTS6L | c.1269G>C p.L423= | Silent (SNP) | VAF 43/153 reads (28%) | called by muse, mutect2, varscan2
- IRX3 | c.387C>G p.S129= | Silent (SNP) | VAF 35/145 reads (24%) | called by muse, mutect2, varscan2
- IRX3 | c.252C>T p.P84= | Silent (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2, varscan2
- KCNA2 | c.1389G>A p.E463= | Silent (SNP) | VAF 43/362 reads (12%) | catalogued as rs751612662; called by muse, mutect2, varscan2
- KCNH1 | c.1410C>A p.A470= (on ENST00000271751 / NM_172362.3; = p.A443= on NM_002238.4) | Silent (SNP) | VAF 82/218 reads (38%) | called by muse, mutect2
- KCNH4 | c.2133A>G p.S711= | Silent (SNP) | VAF 15/94 reads (16%) | called by muse, mutect2, varscan2
- KCNMB1 | c.462C>A p.P154= | Silent (SNP) | VAF 81/478 reads (17%) | catalogued as COSV99211619; called by muse, mutect2, varscan2
- KIF17 | c.2235G>T p.L745= | Silent (SNP) | VAF 13/101 reads (13%) | called by muse, mutect2, varscan2
- KLHL40 | c.984T>A p.A328= | Silent (SNP) | VAF 96/488 reads (20%) | called by muse, mutect2, varscan2
- LRP8 | c.1560C>T p.T520= | Silent (SNP) | VAF 62/688 reads (9%) | called by muse, mutect2
- LTBP1 | c.2430A>G p.S810= (on ENST00000404816 / NM_206943.4; = p.S484= on NM_000627.4) | Silent (SNP) | VAF 65/323 reads (20%) | catalogued as rs767152011; called by muse, mutect2, varscan2
- MAB21L1 | c.546G>A p.R182= | Silent (SNP) | VAF 43/184 reads (23%) | called by muse, mutect2, varscan2
- MAG | c.237A>G p.Q79= | Silent (SNP) | VAF 26/150 reads (17%) | called by muse, mutect2, varscan2
- MMP16 | c.1158G>T p.R386= | Silent (SNP) | VAF 75/506 reads (15%) | catalogued as COSV54154382; called by muse, mutect2, varscan2
- MUC5AC | c.15339G>T p.G5113= | Silent (SNP) | VAF 99/500 reads (20%) | catalogued as COSV100611271; called by muse, mutect2, varscan2
- MUC5B | c.12081C>A p.A4027= | Silent (SNP) | VAF 61/552 reads (11%) | called by muse, varscan2
- MYCBP2 | c.13470T>C p.Y4490= (on ENST00000357337; = p.Y4528= on NM_015057.5) | Silent (SNP) | VAF 114/676 reads (17%) | called by muse, mutect2, varscan2
- MYH1 | c.4581C>A p.I1527= | Silent (SNP) | VAF 83/528 reads (16%) | called by muse, mutect2, varscan2
- MYO18B | c.2031G>T p.L677= | Silent (SNP) | VAF 22/155 reads (14%) | called by muse, mutect2, varscan2
- MYO18B | c.6750C>A p.L2250= | Silent (SNP) | VAF 70/380 reads (18%) | catalogued as COSV100125446; called by muse, mutect2, varscan2
- NAV3 | c.2679C>A p.T893= | Silent (SNP) | VAF 87/524 reads (17%) | called by muse, mutect2, varscan2
- NCAM1 | c.2139C>T p.G713= (on ENST00000316851 / NM_181351.5; = p.G703= on NM_000615.7) | Silent (SNP) | VAF 40/262 reads (15%) | called by muse, mutect2, varscan2
- NLRP7 | c.336G>A p.S112= | Silent (SNP) | VAF 151/767 reads (20%) | catalogued as rs766338217, COSV60173101; called by muse, mutect2, varscan2
- NPAS1 | c.1191T>C p.H397= | Silent (SNP) | VAF 36/148 reads (24%) | catalogued as rs1003099343; called by muse, mutect2, varscan2
- NUP214 | c.1482G>T p.T494= | Silent (SNP) | VAF 48/608 reads (8%) | catalogued as rs147598578, COSV63909334; called by muse, mutect2
- OGDHL | c.306A>G p.S102= | Silent (SNP) | VAF 58/335 reads (17%) | called by muse, mutect2, varscan2
- OR10C1 | c.237C>A p.V79= (on ENST00000622521; = p.V77= on NM_013941.3) | Silent (SNP) | VAF 55/235 reads (23%) | catalogued as rs1245777328; called by muse, mutect2, varscan2
- OR2B11 | c.444C>G p.L148= | Silent (SNP) | VAF 33/225 reads (15%) | called by muse, mutect2, varscan2
- OR2T3 | c.798C>A p.L266= | Silent (SNP) | VAF 203/1164 reads (17%) | catalogued as rs1366516966; called by muse, mutect2, varscan2
- OR2T34 | c.798C>A p.L266= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as rs1381705289; called by muse, mutect2, varscan2
- OR51Q1 | c.243C>A p.P81= | Silent (SNP) | VAF 56/270 reads (21%) | called by muse, mutect2, varscan2
- OR5D18 | c.906C>A p.V302= | Silent (SNP) | VAF 40/230 reads (17%) | catalogued as COSV100450790; called by muse, mutect2, varscan2
- PCDHGA4 | c.723C>T p.L241= | Silent (SNP) | VAF 93/513 reads (18%) | catalogued as rs1245004655; called by muse, mutect2, varscan2
- PDE8B | c.1128G>C p.S376= | Silent (SNP) | VAF 106/775 reads (14%) | catalogued as COSV53732399; called by muse, mutect2, varscan2
- PLA2G2E | c.186C>T p.C62= | Silent (SNP) | VAF 10/173 reads (6%) | called by muse, mutect2
- PPFIBP2 | c.1557G>C p.T519= | Silent (SNP) | VAF 45/257 reads (18%) | catalogued as COSV100206369; called by muse, mutect2, varscan2
- PRR32 | c.751C>A p.R251= | Silent (SNP) | VAF 178/474 reads (38%) | called by muse, mutect2, varscan2
- PTPRB | c.3294C>A p.T1098= | Silent (SNP) | VAF 32/230 reads (14%) | catalogued as COSV54242123; called by muse, mutect2, varscan2
- PXDN | c.2664C>A p.G888= | Silent (SNP) | VAF 31/178 reads (17%) | called by muse, mutect2, varscan2
- RALY | c.210A>T p.A70= | Silent (SNP) | VAF 56/255 reads (22%) | called by muse, mutect2, varscan2
- RANGAP1 | c.294A>T p.P98= | Silent (SNP) | VAF 50/294 reads (17%) | called by muse, mutect2, varscan2
- RBP3 | c.261G>A p.L87= | Silent (SNP) | VAF 82/526 reads (16%) | called by muse, mutect2, varscan2
- RIMBP2 | c.2910C>T p.P970= | Silent (SNP) | VAF 98/486 reads (20%) | called by muse, mutect2, varscan2
- SETDB1 | c.2782C>A p.R928= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as rs746536604, COSV54993957; called by muse, mutect2
- SETDB1 | c.2784G>A p.R928= | Silent (SNP) | VAF 16/62 reads (26%) | called by muse, mutect2
- SEZ6L | c.213C>A p.P71= | Silent (SNP) | VAF 62/457 reads (14%) | catalogued as rs1178676970; called by muse, mutect2, varscan2
- SIGLEC1 | c.1059C>A p.P353= | Silent (SNP) | VAF 12/85 reads (14%) | called by muse, mutect2, varscan2
- SMAD3 | c.984G>T p.P328= | Silent (SNP) | VAF 116/640 reads (18%) | called by muse, mutect2, varscan2
- SP8 | c.96C>T p.P32= (on ENST00000361443 / NM_198956.4; = p.P50= on NM_182700.6) | Silent (SNP) | VAF 110/736 reads (15%) | called by muse, varscan2
- SPAG17 | c.351A>G p.G117= | Silent (SNP) | VAF 67/385 reads (17%) | called by muse, mutect2, varscan2
- TMEM132E | c.264G>T p.P88= | Silent (SNP) | VAF 26/521 reads (5%) | catalogued as rs759706514, COSV58701145; called by muse, mutect2
- TMEM94 | c.2004G>C p.S668= | Silent (SNP) | VAF 49/332 reads (15%) | catalogued as rs770862261; called by muse, mutect2, varscan2
- TRAV12-3 | c.324C>A p.T108= | Silent (SNP) | VAF 34/120 reads (28%) | called by muse, mutect2
- UPP1 | c.732C>T p.V244= | Silent (SNP) | VAF 9/213 reads (4%) | catalogued as rs1391584940; called by muse, mutect2
- XPO5 | c.2367A>T p.P789= | Silent (SNP) | VAF 55/362 reads (15%) | called by muse, mutect2, varscan2
- ZNF585A | c.2103A>G p.K701= (on ENST00000292841 / NM_001288800.2; = p.K646= on NM_152655.3) | Silent (SNP) | VAF 37/211 reads (18%) | called by muse, mutect2, varscan2
- ZNF628 | c.1851G>C p.S617= | Silent (SNP) | VAF 43/225 reads (19%) | called by muse, mutect2, varscan2
- ZNF92 | c.645C>G p.T215= (on ENST00000328747 / NM_152626.4; = p.T146= on NM_007139.4) | Silent (SNP) | VAF 73/479 reads (15%) | called by muse, mutect2, varscan2
- AC044798.1 | n.180A>C | RNA (SNP) | VAF 36/253 reads (14%) | called by muse, mutect2, varscan2
- AC083899.1 | n.3383C>G | RNA (SNP) | VAF 53/616 reads (9%) | called by muse, mutect2, varscan2
- ACP4 | chr19:50799532 C>A | 3'Flank (SNP) | VAF 55/323 reads (17%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73850650 C>A | 3'Flank (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73850651 C>A | 3'Flank (SNP) | VAF 14/56 reads (25%) | called by muse, mutect2, varscan2
- ARHGEF4 | c.428-16236G>T | Intron (SNP) | VAF 85/370 reads (23%) | called by muse, mutect2, varscan2
- C2 | c.849+105A>G | Intron (SNP) | VAF 91/346 reads (26%) | catalogued as rs551391694; called by muse, mutect2, varscan2
- C8orf87 | n.329G>T | RNA (SNP) | VAF 129/718 reads (18%) | called by muse, mutect2, varscan2
- CCDC188 | c.733-19T>C | Intron (SNP) | VAF 4/16 reads (25%) | catalogued as rs73150876; called by mutect2, varscan2
- CERS2 | chr1:150964437 C>T | 3'Flank (SNP) | VAF 22/752 reads (3%) | called by muse, mutect2
- COPS9 | chr2:240136345 C>A | 5'Flank (SNP) | VAF 29/203 reads (14%) | catalogued as COSV56228006; called by muse, mutect2, varscan2
- CPAMD8 | c.2211+10G>T | Intron (SNP) | VAF 20/114 reads (18%) | called by muse, varscan2
- DCD | c.98-417C>A | Intron (SNP) | VAF 88/550 reads (16%) | catalogued as COSV53201234; called by muse, mutect2, varscan2
- DNAH8 | c.-34T>G | 5'UTR (SNP) | VAF 187/722 reads (26%) | called by muse, mutect2, varscan2
- DNM1P34 | n.641C>A | RNA (SNP) | VAF 27/191 reads (14%) | called by muse, mutect2, varscan2
- FBXL13 | c.496-5528C>T | Intron (SNP) | VAF 28/310 reads (9%) | catalogued as rs370703935; called by muse, mutect2
- FOXL2NB | c.220+149G>T | Intron (SNP) | VAF 60/339 reads (18%) | called by muse, mutect2, varscan2
- GPR137B | c.-38G>T | 5'UTR (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2, varscan2
- GRIK3 | c.2565+25C>T | Intron (SNP) | VAF 20/100 reads (20%) | catalogued as COSV100900997; called by muse, mutect2
- HCRTR1 | chr1:31627369 T>C | 3'Flank (SNP) | VAF 70/490 reads (14%) | called by muse, mutect2, varscan2
- HMGA2 | c.249+43226C>A | Intron (SNP) | VAF 63/419 reads (15%) | catalogued as rs1011689127; called by muse, mutect2, varscan2
- HMGCS2 | c.686-46T>A | Intron (SNP) | VAF 143/739 reads (19%) | catalogued as rs1217461461; called by muse, mutect2, varscan2
- HPS4 | c.669+27G>T | Intron (SNP) | VAF 80/395 reads (20%) | called by muse, mutect2, varscan2
- KCNC1 | chr11:17779550 C>A | 3'Flank (SNP) | VAF 40/264 reads (15%) | called by muse, mutect2, varscan2
- KRTAP2-1 | c.*50C>A | 3'UTR (SNP) | VAF 31/349 reads (9%) | catalogued as rs367819282; called by muse, varscan2
- NFKBID | c.607-181G>T | Intron (SNP) | VAF 47/209 reads (22%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.184G>T | RNA (SNP) | VAF 47/174 reads (27%) | called by muse, mutect2, varscan2
- NSD2 | c.2138-109A>C | Intron (SNP) | VAF 55/289 reads (19%) | called by muse, mutect2, varscan2
- OSGIN1 | n.1781C>T | RNA (SNP) | VAF 55/305 reads (18%) | catalogued as rs201931617; called by muse, mutect2, varscan2
- PCDHGA3 | c.2425-68037G>T | Intron (SNP) | VAF 24/574 reads (4%) | called by muse, mutect2
- PPFIBP2 | chr11:7656791 G>T | 3'Flank (SNP) | VAF 85/443 reads (19%) | called by muse, mutect2, varscan2
- PPFIBP2 | chr11:7656792 G>T | 3'Flank (SNP) | VAF 84/437 reads (19%) | called by muse, mutect2, varscan2
- PRSS40A | n.142-2328G>T | Intron (SNP) | VAF 32/304 reads (11%) | called by mutect2, varscan2
- RASGRF2 | c.1390+314G>A | Intron (SNP) | VAF 93/574 reads (16%) | called by muse, mutect2, varscan2
- REEP2 | c.-93G>T | 5'UTR (SNP) | VAF 13/44 reads (30%) | called by muse, mutect2, varscan2
- SLC43A2 | c.1079-899G>T | Intron (SNP) | VAF 17/102 reads (17%) | called by muse, mutect2, varscan2
- STK26 | c.-23G>T | 5'UTR (SNP) | VAF 84/222 reads (38%) | catalogued as rs1423057522; called by muse, mutect2, varscan2
- SUSD4 | c.148+3018C>A | Intron (SNP) | VAF 63/194 reads (32%) | called by muse, mutect2, varscan2
- SYTL2 | c.1459+2437A>T | Intron (SNP) | VAF 43/218 reads (20%) | catalogued as COSV100314533; called by muse, mutect2, varscan2
- TAC3 | c.-135C>A | 5'UTR (SNP) | VAF 64/309 reads (21%) | catalogued as rs958727406; called by muse, mutect2, varscan2
- TMEM270 | c.-11G>T | 5'UTR (SNP) | VAF 48/233 reads (21%) | catalogued as rs1554639174, COSV100260282; called by muse, mutect2, varscan2
- TTLL7 | c.-372G>A | 5'UTR (SNP) | VAF 28/177 reads (16%) | called by muse, mutect2, varscan2
- USH1C | c.1285-45A>C | Intron (SNP) | VAF 15/65 reads (23%) | called by muse, mutect2, varscan2
- VPS35L | chr16:19555606 C>A | 5'Flank (SNP) | VAF 53/330 reads (16%) | catalogued as rs764999552; called by muse, mutect2, varscan2
